Somatic mutation profile of tumor specimen TCGA-V1-A9ZG-01A (aliquot TCGA-V1-A9ZG-01A-11D-A41K-08) from TCGA case TCGA-V1-A9ZG, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9ZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fbabe00-1fab-4d94-b64b-0e7080784aa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9ZG-10A (Blood Derived Normal), aliquot TCGA-V1-A9ZG-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a03bac84-1cb5-47cf-82c7-12a22a2207fd

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 17, Silent 8, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.3745C>T p.R1249W | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62390129; called by muse, mutect2, varscan2
- CPT1B | c.1736T>G p.F579C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100376441; called by muse, mutect2, varscan2
- DMBT1 | c.3238C>T p.H1080Y (on ENST00000338354 / NM_001377530.1; = p.H581Y on NM_004406.3) | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV57539449, COSV57551510; called by muse, mutect2, varscan2
- EEF2KMT | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as rs770940503, COSV69863272; called by muse, mutect2, varscan2
- EIF5A | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV100222612; called by muse, mutect2, varscan2
- GTF2H3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs374279157, COSV99967476; called by muse, mutect2, varscan2
- IFNLR1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100551946; called by muse, mutect2, varscan2
- LRRC36 | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99338360; called by muse, mutect2, varscan2
- LYST | c.9208G>A p.E3070K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101087842; called by muse, mutect2, varscan2
- MAOB | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.917); catalogued as COSV100955866; called by muse, mutect2, varscan2
- MICAL2 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs776677527, COSV99816575; called by muse, mutect2, varscan2
- NETO1 | c.396T>A p.F132L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100198066; called by muse, mutect2, varscan2
- PALLD | c.2831T>G p.L944R (on ENST00000505667 / NM_001166108.2; = p.L927R on NM_016081.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99823650; called by muse, mutect2, varscan2
- RSPO1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs143117795, COSV100740457; called by muse, mutect2, varscan2
- SMARCAL1 | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV100619702; called by muse, mutect2, varscan2
- TCF3 | c.1874del p.K625Rfs*20 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as rs1291500795; called by mutect2, pindel, varscan2
- VEPH1 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100747268; called by muse, mutect2, varscan2
- ZFHX3 | c.4147G>T p.E1383* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99194988, COSV99212558; called by muse, mutect2, varscan2
- ZFP3 | c.1398A>G p.I466M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as COSV100603660; called by muse, mutect2, varscan2
- ATP13A2 | c.2796C>T p.S932= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs755542233, COSV100453843; called by muse, mutect2
- COL4A3 | c.4431A>G p.Q1477= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV101169774; called by muse, mutect2, varscan2
- DYSF | c.4989C>T p.V1663= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs778238756, COSV99243632; ClinVar: likely benign; called by mutect2, varscan2
- FGL2 | c.606A>T p.S202= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99592019; called by muse, mutect2, varscan2
- GANC | c.600A>G p.G200= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100530615; called by muse, mutect2, varscan2
- OAS3 | c.849C>T p.F283= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99965968; called by muse, mutect2, varscan2
- OR5A1 | c.27C>T p.S9= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100118222; called by muse, mutect2, varscan2
- PRDM10 | c.999G>T p.V333= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100456525; called by mutect2, varscan2
